Somatic mutation profile of tumor specimen TCGA-44-3918-01A (aliquot TCGA-44-3918-01A-01D-1105-08) from TCGA case TCGA-44-3918, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.9 years (22,236 days).
Specimen TCGA-44-3918-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33467953-393f-4b0b-82f0-6714ce0b75f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-3918-10A (Blood Derived Normal), aliquot TCGA-44-3918-10A-01D-A271-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4236883f-0c7e-442e-822e-86fc41b8dbe3

The open-access MAF lists 961 somatic variants for this specimen: 749 protein-altering or splice-affecting, 187 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 640, Silent 187, Nonsense Mutation 48, Splice Site 23, Frame Shift Del 21, Intron 10, Frame Shift Ins 9, RNA 8, Splice Region 6, 5'UTR 3, 3'Flank 2, Nonstop Mutation 2.

Variants (750 of 961; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2991G>T p.R997S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs755501749, COSV62203559; ClinVar: likely pathogenic; called by mutect2, varscan2
- SCN5A | c.3718G>C p.E1240Q (on ENST00000333535 / NM_198056.3; = p.E1239Q on NM_000335.5) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs199473211, CM024648; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- TP53 | c.920-2A>G p.X307_splice | Splice Site (SNP) | VAF 35/126 reads (28%) | hotspot (GDC flag); catalogued as rs397516439, COSV52693974, COSV52706655, COSV52945558, COSV53066011; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1820C>G p.T607S (on ENST00000272895 / NM_173076.3; = p.T289S on NM_015657.3) | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV55959662; called by muse, mutect2, varscan2
- ABCA13 | c.6778A>G p.I2260V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs770312852, COSV70028933; called by muse, mutect2, varscan2
- ABCA7 | c.5521A>T p.T1841S | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV54029678; called by muse, mutect2, varscan2
- ABCC4 | c.647G>T p.W216L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV65312829; called by muse, mutect2, varscan2
- ABI3BP | c.1235C>A p.P412Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52536514; called by muse, mutect2, varscan2
- ABRACL | c.31G>C p.V11L | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as COSV62771505; called by muse, mutect2, varscan2
- AC136428.1 | c.329del p.T110Rfs*7 | Frame Shift Del (DEL) | VAF 58/343 reads (17%) | catalogued as COSV101434976; called by mutect2, pindel, varscan2
- ACSM2A | c.1710G>A p.M570I (on ENST00000219054; = p.M491I on NM_001308169.2) | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs757378811, COSV54584726, COSV99525284; called by muse, mutect2, varscan2
- ACVR2A | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | catalogued as COSV54022625; called by muse, mutect2, varscan2
- ADAMTS12 | c.2267G>T p.G756V | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61263232, COSV61272776; called by muse, mutect2, varscan2
- ADAMTS3 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711400; called by muse, varscan2
- ADAMTS4 | c.1090+2T>A p.X364_splice | Splice Site (SNP) | VAF 70/230 reads (30%) | catalogued as COSV63487845; called by muse, mutect2, varscan2
- ADAMTS6 | c.2705A>T p.E902V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.206); catalogued as COSV100068460, COSV58682898; called by muse, mutect2, varscan2
- ADAMTS7 | c.4282G>T p.G1428C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101183136; called by muse, mutect2, varscan2
- ADAMTSL1 | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV52815817, COSV52820281; called by muse, mutect2, varscan2
- ADCY8 | c.2017C>A p.H673N | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.579); catalogued as COSV53908148; called by muse, mutect2, varscan2
- AIM2 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV63699769; called by muse, varscan2
- AKAP4 | c.1194G>T p.M398I | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62074455; called by muse, mutect2, varscan2
- AKR1D1 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54337201; called by muse, varscan2
- ALG10 | c.155A>T p.H52L | Missense Mutation (SNP) | VAF 66/636 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV56792587; called by muse, varscan2
- ALG10 | c.311G>C p.S104T | Missense Mutation (SNP) | VAF 38/341 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.28); catalogued as COSV56792602; called by muse, mutect2, varscan2
- ALG8 | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as rs886048687, COSV55200425; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH3 | c.732G>C p.L244F | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57024106; called by muse, mutect2, varscan2
- ALKBH4 | c.796G>T p.V266F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52960958, COSV52962193; called by mutect2, varscan2
- ALOX12 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.368); catalogued as COSV52349732; called by muse, mutect2
- ALPK2 | c.5723G>T p.S1908I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100864502; called by muse, mutect2, varscan2
- AMER1 | c.1737G>T p.E579D | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV57660921; called by muse, mutect2, varscan2
- AMOT | c.2401C>A p.H801N (on ENST00000371959 / NM_001113490.1; = p.H392N on NM_133265.3) | Missense Mutation (SNP) | VAF 35/409 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100495365, COSV59063376; called by muse, mutect2
- ANGEL1 | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV51873377; called by muse, mutect2, varscan2
- ANK1 | c.5325G>T p.R1775S | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV55881860, COSV55897567; called by muse, mutect2
- ANK1 | c.3962A>T p.N1321I | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV55881874; called by muse, mutect2, varscan2
- ANK2 | c.3389G>T p.S1130I | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV52161632; called by muse, varscan2
- ANK2 | c.6940G>T p.G2314C | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV52161652; called by muse, mutect2, varscan2
- ANKRD27 | c.2656-1G>T p.X886_splice | Splice Site (SNP) | VAF 52/269 reads (19%) | catalogued as COSV100042934; called by muse, mutect2, varscan2
- ANKRD30A | c.3487C>A p.Q1163K (on ENST00000611781; = p.Q1107K on NM_052997.2) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV100653796, COSV64614228; called by muse, mutect2, varscan2
- ANO5 | c.1088G>T p.W363L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV61085083; called by muse, mutect2
- AP002512.3 | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as rs1050088418, COSV54408074, COSV99687833; called by muse, mutect2, varscan2
- APCS | c.205T>C p.F69L | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99661365; called by muse, mutect2, varscan2
- APOB | c.4648C>A p.L1550M | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51935541; called by muse, mutect2, varscan2
- APP | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs532382285, COSV100695946; called by muse, mutect2, varscan2
- AQP3 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV99955608; called by muse, mutect2
- ARHGAP25 | c.476G>T p.G159V (on ENST00000409202 / NM_001007231.3; = p.G151V on NM_014882.3) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1346473805, COSV54902400; called by muse, mutect2, varscan2
- ARHGAP36 | c.1559C>A p.P520H | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV52266861; called by muse, mutect2, varscan2
- ARHGAP44 | c.1448G>T p.R483L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV52394208; called by muse, mutect2, varscan2
- ARHGEF12 | c.3454G>A p.G1152R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.64); catalogued as COSV63104725; called by muse, mutect2, varscan2
- ARHGEF5 | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 78/507 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV99282915; called by muse, mutect2, varscan2
- ASAH2 | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as rs753939262; called by muse, mutect2, varscan2
- ASB7 | c.616A>T p.T206S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV58403792; called by muse, mutect2, varscan2
- ATP10B | c.1382-1G>T p.X461_splice | Splice Site (SNP) | VAF 22/139 reads (16%) | catalogued as COSV58778826; called by muse, mutect2, varscan2
- ATP2B3 | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684905; called by muse, mutect2
- ATP8B3 | c.1941G>A p.L647= | Splice Region (SNP) | VAF 10/142 reads (7%) | catalogued as COSV59542829; called by muse, mutect2
- BACH2 | c.1499G>T p.C500F | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1203834121, COSV57592641; called by muse, mutect2, varscan2
- BCL11A | c.913A>T p.M305L (on ENST00000335712 / NM_001365609.1; = p.M339L on NM_018014.4) | Missense Mutation (SNP) | VAF 104/368 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.455); catalogued as COSV59630199; called by muse, mutect2, varscan2
- BIRC6 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV70199350; called by muse, mutect2, varscan2
- BMP3 | c.1292G>C p.G431A | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51084396, COSV99262028; called by muse, mutect2, varscan2
- BPIFB3 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV64957351; called by muse, mutect2, varscan2
- BPIFC | c.1503G>T p.W501C | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV53278808; called by muse, mutect2, varscan2
- BRAF | c.338G>T p.S113I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV56184190; called by muse, mutect2, varscan2
- BRINP3 | c.2294G>T p.C765F | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66524511; called by muse, mutect2
- BRINP3 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV100819047; called by muse, mutect2, varscan2
- BRINP3 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV66514914, COSV66524518; called by muse, mutect2, varscan2
- BTD | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs1310040913, COSV57729167; called by muse, mutect2, varscan2
- BTN3A3 | c.1442C>G p.S481C | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55071989; called by muse, mutect2
- C12orf45 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55012755; called by muse, mutect2
- C12orf50 | c.949A>T p.K317* | Nonsense Mutation (SNP) | VAF 14/154 reads (9%) | catalogued as COSV53895315; called by muse, mutect2
- C12orf71 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs549676884, COSV70282696; called by muse, mutect2, varscan2
- C1orf74 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV50553128; called by muse, mutect2, varscan2
- CA9 | c.622C>G p.P208A | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV65675709; called by muse, mutect2, varscan2
- CACNA1C | c.4881C>A p.Y1627* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV59719675, COSV59721841; called by muse, mutect2, varscan2
- CACNA1H | c.2566C>A p.P856T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61986444; called by muse, mutect2
- CACNA1S | c.2333C>G p.S778C | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV62936832, COSV62939574; called by muse, mutect2, varscan2
- CACNA2D1 | c.862T>A p.F288I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV62379814; called by muse, mutect2
- CALD1 | c.1538C>G p.P513R (on ENST00000361675 / NM_033138.4; = p.P258R on NM_004342.7) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.351); catalogued as COSV100724360; called by muse, mutect2, varscan2
- CAPN2 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770020884, COSV54335388, COSV54336190; called by muse, mutect2, varscan2
- CARMIL2 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.921); catalogued as COSV58026371; called by muse, mutect2, varscan2
- CARNS1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.549); catalogued as COSV57130853; called by muse, mutect2, varscan2
- CASP2 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60082290; called by muse, mutect2, varscan2
- CASP8AP2 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs369918159; called by muse, mutect2, varscan2
- CATSPER2 | c.175G>T p.G59* | Nonsense Mutation (SNP) | VAF 58/211 reads (27%) | catalogued as COSV100391106, COSV58660859; called by muse, mutect2, varscan2
- CCDC106 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1382981596, COSV54401812; called by muse, mutect2, varscan2
- CCDC141 | c.3893C>A p.P1298H | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as COSV99837007; called by muse, mutect2, varscan2
- CCDC141 | c.3611A>T p.E1204V | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV55384719; called by muse, mutect2, varscan2
- CCDC63 | c.172A>T p.S58C | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV57528593; called by muse, mutect2
- CCER1 | c.255G>T p.W85C | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62646613, COSV62646877; called by muse, mutect2, varscan2
- CCL22 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV54660183; called by muse, mutect2, varscan2
- CCNB3 | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV52073852; called by muse, mutect2, varscan2
- CCS | c.489G>T p.R163= | Splice Region (SNP) | VAF 24/206 reads (12%) | catalogued as COSV59579125; called by muse, mutect2, varscan2
- CCT7 | c.1250C>A p.S417Y | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99240908; called by muse, mutect2, varscan2
- CD207 | c.799G>T p.V267L | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV101338566; called by muse, mutect2, varscan2
- CD207 | c.798G>T p.W266C | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101338569; called by muse, mutect2
- CD248 | c.1563T>A p.Y521* | Nonsense Mutation (SNP) | VAF 25/154 reads (16%) | catalogued as COSV60936501; called by muse, mutect2, varscan2
- CD33 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51801870; called by muse, mutect2, varscan2
- CD80 | c.148T>C p.C50R | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99958316; called by muse, mutect2
- CD86 | c.541G>T p.E181* (on ENST00000330540 / NM_175862.5; = p.E175* on NM_006889.4) | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | catalogued as COSV52606953; called by muse, mutect2, varscan2
- CDC20B | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV57052295; called by muse, mutect2, varscan2
- CDCP1 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 45/401 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.041); catalogued as COSV56105494; called by muse, mutect2, varscan2
- CDH10 | c.344G>T p.R115M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs780636248, COSV52579582, COSV52581080; called by muse, mutect2, varscan2
- CDH10 | c.50C>A p.P17Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as COSV52581087; called by muse, mutect2, varscan2
- CDH18 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV56923022; called by muse, mutect2, varscan2
- CDH4 | c.458T>A p.L153Q | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV64654965; called by muse, mutect2
- CDH6 | c.2279C>A p.A760E | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54070182; called by muse, mutect2, varscan2
- CECR2 | c.820C>G p.L274V (on ENST00000342247 / NM_001290047.2; = p.L111V on NM_001290046.1) | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV52841295; called by muse, mutect2
- CENPC | c.1750G>C p.A584P | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99894111; called by muse, mutect2, varscan2
- CENPE | c.4150A>G p.S1384G | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54381268; called by muse, mutect2, varscan2
- CEP112 | c.2231G>T p.R744L | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV67139630; called by muse, mutect2
- CEP128 | c.2238G>T p.M746I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55377059; called by muse, mutect2, varscan2
- CEP250 | c.4688A>T p.E1563V | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV61170166; called by muse, mutect2, varscan2
- CFHR4 | c.216C>A p.C72* (on ENST00000367416 / NM_001201551.2; = p.C73* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 11/133 reads (8%) | catalogued as rs1246360223, COSV52228741; called by muse, mutect2
- CHD6 | c.3332G>T p.R1111L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58557210; called by muse, mutect2
- CHD8 | c.4768G>T p.E1590* (on ENST00000646647 / NM_001170629.2; = p.E1311* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 116/471 reads (25%) | catalogued as rs1555314199, COSV63219132; called by muse, mutect2, varscan2
- CHGB | c.1069C>A p.L357M | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV66760514; called by muse, mutect2, varscan2
- CHRND | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV51323192; called by muse, mutect2
- CHRND | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51319277; called by muse, mutect2, varscan2
- CHSY3 | c.2539T>C p.Y847H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100519442; called by muse, mutect2, varscan2
- CLCN2 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV55601183, COSV55603037; called by muse, mutect2, varscan2
- CLDN17 | c.135G>C p.R45S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.593); catalogued as COSV54523053, COSV54523229; called by muse, mutect2, varscan2
- CLDN8 | c.103T>A p.F35I | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99729882; called by muse, mutect2, varscan2
- CLEC1B | c.440A>T p.E147V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV53725508; called by muse, mutect2, varscan2
- CLVS1 | c.796T>G p.F266V | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1411168887, COSV57975062; called by muse, mutect2, varscan2
- CLYBL | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59221834; called by muse, mutect2, varscan2
- CNN3 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.092); catalogued as COSV54730215; called by muse, mutect2, varscan2
- CNOT6 | c.1462G>T p.G488C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56161591; called by muse, mutect2, varscan2
- CNTNAP5 | c.1828G>T p.G610C | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV70486363; called by muse, mutect2, varscan2
- COA7 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV65299517; called by muse, mutect2, varscan2
- COL13A1 | c.921C>A p.D307E (on ENST00000398978 / NM_001130103.2; = p.D250E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.291); catalogued as COSV62569906; called by muse, mutect2, varscan2
- COL15A1 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66644876; called by muse, mutect2, varscan2
- COL1A1 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV56804974, COSV99867805; called by muse, mutect2, varscan2
- COL24A1 | c.2029C>A p.P677T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV65306506; called by muse, mutect2, varscan2
- COL24A1 | c.1491+1G>T p.X497_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99054664; called by muse, mutect2, varscan2
- COL4A1 | c.4277G>T p.G1426V | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101010940, COSV65425807; called by muse, mutect2, varscan2
- COL4A2 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 44/165 reads (27%) | catalogued as rs768030086, COSV64628383; called by muse, mutect2, varscan2
- COL4A6 | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 82/327 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57866824; called by muse, mutect2, varscan2
- COL6A5 | c.7069C>A p.L2357M (on ENST00000312481; = p.L2353M on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.542); catalogued as COSV55202037; called by muse, mutect2, varscan2
- CORO1C | c.1213G>T p.V405F | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV54595961; called by muse, mutect2, varscan2
- CPB1 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV51573505; called by muse, mutect2, varscan2
- CPE | c.443G>C p.S148T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV68580348; called by muse, mutect2, varscan2
- CPE | c.945C>A p.N315K | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68580353; called by muse, mutect2, varscan2
- CPN2 | c.761C>A p.T254K | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV60470445; called by muse, varscan2
- CPNE6 | c.1415G>C p.G472A | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53744183; called by muse, mutect2, varscan2
- CR1 | c.3208C>A p.P1070T | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65458255; called by muse, mutect2, varscan2
- CRISP1 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100237090, COSV59993662; called by muse, mutect2, varscan2
- CSMD3 | c.10901C>T p.A3634V (on ENST00000297405 / NM_001363185.1; = p.A3465V on NM_052900.3) | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52172348; called by muse, mutect2, varscan2
- CSMD3 | c.10681G>T p.V3561L (on ENST00000297405 / NM_001363185.1; = p.V3392L on NM_052900.3) | Missense Mutation (SNP) | VAF 27/369 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV52145425; called by muse, mutect2
- CSMD3 | c.7754G>T p.G2585V (on ENST00000297405 / NM_001363185.1; = p.G2481V on NM_052900.3) | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs141864545, COSV99838070; called by muse, mutect2, varscan2
- CSMD3 | c.7753G>T p.G2585C (on ENST00000297405 / NM_001363185.1; = p.G2481C on NM_052900.3) | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99838074; called by muse, mutect2, varscan2
- CST1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.392); catalogued as COSV59054876; called by muse, mutect2, varscan2
- CTCF | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50468940; called by muse, mutect2, varscan2
- CTNND2 | c.1515G>T p.Q505H | Missense Mutation (SNP) | VAF 23/287 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV58878500; called by muse, mutect2
- CTSG | c.722C>G p.T241R | Missense Mutation (SNP) | VAF 59/601 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53535493; called by muse, mutect2, varscan2
- CTXN3 | c.161A>G p.D54G | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101060690; called by muse, mutect2, varscan2
- CUL3 | c.1843G>T p.E615* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV52364897; called by muse, mutect2, varscan2
- CYC1 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.181); catalogued as rs756155043, COSV100010471; called by muse, mutect2, varscan2
- CYP2A13 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs1345829055, COSV57837826; called by muse, mutect2, varscan2
- CYP46A1 | c.283-2A>G p.X95_splice | Splice Site (SNP) | VAF 141/685 reads (21%) | catalogued as COSV55894557; called by muse, mutect2, varscan2
- CYP4F3 | c.1152C>A p.C384* | Nonsense Mutation (SNP) | VAF 21/186 reads (11%) | catalogued as COSV55409919, COSV55410605; called by muse, mutect2, varscan2
- DCAF12L2 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV100758920, COSV63581726; called by muse, mutect2, varscan2
- DCLRE1A | c.1090A>T p.S364C | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV63748739; called by muse, mutect2, varscan2
- DDX24 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 44/332 reads (13%) | catalogued as COSV58212504; called by muse, mutect2, varscan2
- DDX31 | c.1692G>T p.Q564H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60135946; called by muse, mutect2, varscan2
- DEF8 | c.599A>T p.H200L (on ENST00000268676 / NM_207514.3; = p.H139L on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51919147; called by muse, mutect2, varscan2
- DEF8 | c.1003A>T p.S335C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV51919169; called by muse, mutect2, varscan2
- DENND5A | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60233689; called by muse, mutect2, varscan2
- DHFR2 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV100113332; called by muse, mutect2, varscan2
- DHX57 | c.2164G>T p.G722C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772920040, COSV54885442; called by muse, mutect2, varscan2
- DIP2C | c.2413A>G p.N805D | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1444301709, COSV55158482; called by muse, mutect2, varscan2
- DISP1 | c.1948A>G p.T650A | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.888); catalogued as COSV52659027; called by muse, mutect2, varscan2
- DLX2 | c.663C>A p.H221Q | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.446); catalogued as COSV52232141; called by muse, mutect2, varscan2
- DMD | c.8545A>G p.R2849G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs1267267091, COSV58911659; called by muse, mutect2, varscan2
- DMTF1 | c.1439A>T p.D480V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58685333; called by muse, mutect2, varscan2
- DNAAF6 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV60495835; called by muse, mutect2, varscan2
- DNAH5 | c.11117A>T p.E3706V | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54225178; called by muse, mutect2
- DNAH7 | c.8923A>G p.I2975V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.035); catalogued as rs1011061194, COSV56765280; called by muse, mutect2
- DNHD1 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as rs1476186357, COSV54435846; called by muse, mutect2
- DOCK7 | c.3630G>C p.K1210N (on ENST00000635253 / NM_001367561.1; = p.K1179N on NM_033407.3) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as COSV52005756; called by muse, mutect2, varscan2
- DOCK9 | c.5142G>T p.M1714I (on ENST00000376460 / NM_001366676.2; = p.M1715I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV59629582; called by muse, mutect2, varscan2
- DPYSL3 | c.674T>A p.L225Q | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.955); catalogued as COSV58326825; called by muse, mutect2, varscan2
- DRC1 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV56531393; called by muse, mutect2, varscan2
- DSC3 | c.300C>A p.D100E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs754314173, COSV64572228; called by muse, mutect2, varscan2
- DSCAM | c.1876A>G p.I626V | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV68026847; called by muse, mutect2
- DSCAML1 | c.3410C>G p.S1137C (on ENST00000321322; = p.S1077C on NM_020693.4) | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58390849; called by muse, mutect2, varscan2
- DSG1 | c.2649G>T p.M883I | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57135341; called by muse, mutect2
- DSTYK | c.1255A>G p.M419V | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV65686529; called by muse, mutect2
- DUOX2 | c.3817A>T p.S1273C | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV66532167; called by muse, mutect2, varscan2
- DUSP9 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.086); catalogued as COSV61437994; called by muse, mutect2, varscan2
- E2F7 | c.2355G>T p.L785F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs745894339, COSV59740047; called by muse, mutect2, varscan2
- ECPAS | c.2908C>T p.H970Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV52197322; called by muse, mutect2, varscan2
- ECPAS | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV52197354; called by muse, mutect2, varscan2
- EDDM3A | c.444G>C p.*148Yext*89 | Nonstop Mutation (SNP) | VAF 9/125 reads (7%) | catalogued as COSV100473385; called by muse, mutect2
- EDN3 | c.637C>A p.P213T (on ENST00000337938 / NM_001302455.2; = p.P199T on NM_207033.3) | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.084); catalogued as COSV61108005; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62567906; called by muse, varscan2
- EFCAB12 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.218); catalogued as COSV58176335; called by muse, mutect2, varscan2
- EFCAB5 | c.4412T>C p.I1471T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV57930126; called by muse, mutect2, varscan2
- EFTUD2 | c.2439G>C p.R813S | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53655621; called by muse, mutect2, varscan2
- EHMT1 | c.3836A>C p.Q1279P | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV66044733; called by muse, varscan2
- ELFN2 | c.1013C>A p.T338N | Missense Mutation (SNP) | VAF 46/401 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV68744586; called by muse, mutect2, varscan2
- ELOA2 | c.43C>A p.Q15K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99797010; called by muse, mutect2, varscan2
- ELSPBP1 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV60413711, COSV60413980; called by muse, mutect2, varscan2
- EMC3 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as COSV55278183; called by muse, mutect2
- EMG1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1555152823, COSV54642042; called by muse, mutect2, varscan2
- ENG | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61227481; called by muse, mutect2
- ENGASE | c.1700+1G>A p.X567_splice | Splice Site (SNP) | VAF 14/85 reads (16%) | catalogued as COSV56135543; called by muse, mutect2, varscan2
- ENOX1 | c.893G>C p.R298P | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54894307, COSV54899477; called by muse, mutect2, varscan2
- EPHB1 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67661786; called by muse, mutect2, varscan2
- EPN2 | c.1584G>T p.R528S | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV59061242; called by muse, mutect2, varscan2
- ERCC4 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as rs749688539, COSV61312088; called by muse, mutect2, varscan2
- ESRRB | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV55061196, COSV55061619; called by muse, mutect2, varscan2
- EVI2B | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100445539; called by muse, mutect2, varscan2
- EVPL | c.1391G>T p.C464F | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56911034; called by muse, mutect2, varscan2
- EYA1 | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 26/424 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV58160277; called by muse, mutect2
- FAHD2B | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 28/204 reads (14%) | catalogued as COSV55630679; called by muse, varscan2
- FAM114A2 | c.1117G>C p.D373H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV61077887; called by muse, mutect2
- FAM135A | c.3031G>C p.E1011Q (on ENST00000370479 / NM_001351599.1; = p.E798Q on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.432); catalogued as COSV52051610; called by muse, mutect2, varscan2
- FAM13C | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV53248501; called by muse, mutect2, varscan2
- FAM171A1 | c.2593G>T p.D865Y | Missense Mutation (SNP) | VAF 96/548 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV65316156, COSV65317426; called by muse, mutect2, varscan2
- FAM47A | c.2238G>C p.K746N | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100649747, COSV60496724, COSV60498855; called by muse, mutect2, varscan2
- FANCM | c.3745A>G p.T1249A | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1448270737, COSV57501264; called by muse, mutect2, varscan2
- FANCM | c.5014G>A p.D1672N | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1016099459, COSV57501278; called by muse, mutect2, varscan2
- FASN | c.3238G>T p.V1080L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV60754886; called by muse, mutect2, varscan2
- FASTKD5 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs754360558, COSV53906170; called by muse, mutect2, varscan2
- FAT2 | c.10481A>T p.Q3494L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs1210627644, COSV55819862; called by muse, mutect2, varscan2
- FAT3 | c.6943G>T p.D2315Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447557458, COSV53111232; called by muse, mutect2, varscan2
- FAT3 | c.12814C>T p.R4272C | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1438591331, COSV53111253; called by muse, mutect2, varscan2
- FAT4 | c.3934A>T p.T1312S | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV67886852; called by muse, mutect2, varscan2
- FBN2 | c.1084A>T p.R362* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV52513670; called by muse, mutect2, varscan2
- FBN3 | c.3960C>T p.H1320= | Splice Region (SNP) | VAF 16/103 reads (16%) | catalogued as rs541778651, COSV54460858; called by muse, mutect2
- FCRL5 | c.2408C>A p.A803E | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.338); catalogued as COSV62511437, COSV62514578; called by muse, mutect2, varscan2
- FER1L6 | c.3289G>T p.A1097S | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV67549939; called by muse, mutect2, varscan2
- FGF14 | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV65943974; called by muse, mutect2, varscan2
- FHDC1 | c.2186G>C p.R729T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52599697; called by mutect2, varscan2
- FHOD3 | c.1029G>T p.R343S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV57173577; called by muse, mutect2, varscan2
- FLG | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 96/1398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64237433; called by muse, mutect2
- FLG | c.1250C>G p.S417C | Missense Mutation (SNP) | VAF 134/986 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757753733, COSV64241926; called by muse, mutect2, varscan2
- FMN2 | c.4311C>A p.F1437L | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60430678; called by muse, mutect2, varscan2
- FNDC7 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54753755; called by muse, mutect2, varscan2
- FNIP2 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 81/463 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.166); catalogued as COSV52439895; called by muse, mutect2, varscan2
- FOLH1 | c.2104G>A p.G702R | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57049272; called by muse, mutect2, varscan2
- FSHR | c.2011C>A p.H671N | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.258); catalogued as COSV100437452; called by mutect2, varscan2
- FSHR | c.1231A>G p.I411V | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV58623867; called by muse, mutect2, varscan2
- FSTL5 | c.2007C>A p.S669R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.102); catalogued as COSV60196021, COSV60223489; called by muse, mutect2, varscan2
- FUT10 | c.929G>C p.S310T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV59451710; called by muse, mutect2, varscan2
- FYTTD1 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV54083338; called by muse, mutect2
- GABRA6 | c.1310G>T p.W437L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50881580; called by muse, varscan2
- GABRD | c.945G>T p.W315C | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV66080610; called by muse, mutect2, varscan2
- GABRQ | c.1135C>A p.Q379K | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV64782064; called by muse, mutect2, varscan2
- GAL3ST4 | c.866G>C p.W289S | Missense Mutation (SNP) | VAF 26/343 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.371); catalogued as COSV57586431; called by muse, mutect2
- GALNT1 | c.1490G>T p.C497F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52452351; called by muse, mutect2, varscan2
- GALNT16 | c.864-2A>T p.X288_splice | Splice Site (SNP) | VAF 22/87 reads (25%) | catalogued as COSV61886034; called by muse, mutect2, varscan2
- GALNTL6 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV72552982; called by muse, mutect2
- GAN | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV73720901; called by muse, mutect2, varscan2
- GBX2 | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV60445270; called by muse, mutect2, varscan2
- GCNT2 | c.1173G>T p.Q391H (on ENST00000379597 / NM_001374747.1; = p.Q389H on NM_001491.3) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53942348; called by muse, varscan2
- GDPD4 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60019412; called by muse, mutect2, varscan2
- GLDC | c.2875C>A p.H959N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs757705918, COSV58680124; called by muse, mutect2, varscan2
- GPC2 | c.564C>A p.Y188* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV52785086; called by muse, mutect2, varscan2
- GPC3 | c.1516A>T p.I506F | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.284); catalogued as COSV63664299; called by muse, mutect2, varscan2
- GPC6 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV65512233; called by muse, mutect2, varscan2
- GPR158 | c.2338G>T p.G780C | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs369542883, COSV66270468; called by muse, mutect2, varscan2
- GPR179 | c.3854G>A p.G1285D (on ENST00000621958; = p.G1284D on NM_001004334.4) | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1349066788; called by muse, mutect2, varscan2
- GRHL1 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV61408239; called by muse, mutect2
- GRID2 | c.1467C>A p.Y489* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as COSV56207010, COSV56233184; called by muse, mutect2, varscan2
- GRIN2B | c.2567G>T p.G856V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74205955; called by muse, mutect2, varscan2
- GRK4 | c.971-1G>T p.X324_splice (on ENST00000398052 / NM_182982.3; = p.X292_splice on NM_005307.3) | Splice Site (SNP) | VAF 21/154 reads (14%) | catalogued as COSV100584113; called by muse, mutect2, varscan2
- GRK4 | c.971G>T p.G324V (on ENST00000398052 / NM_182982.3; = p.G292V on NM_005307.3) | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100584114; called by muse, mutect2, varscan2
- GRM1 | c.3459C>A p.D1153E | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51149372; called by muse, mutect2, varscan2
- GRM3 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64471897, COSV64478074; called by muse, mutect2
- GRM4 | c.1111C>A p.H371N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100946407; called by muse, mutect2, varscan2
- GRM4 | c.1110C>A p.F370L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100946416; called by muse, mutect2, varscan2
- GSDMD | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.582); catalogued as COSV52797219; called by muse, varscan2
- HAND2 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as COSV100854200; called by muse, mutect2
- HARS2 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV51227021; called by muse, mutect2
- HAUS5 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV52547955; called by muse, mutect2
- HCFC2 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV57558685; called by muse, mutect2, varscan2
- HDAC7 | c.1232C>T p.T411I (on ENST00000427332; = p.T450I on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.397); catalogued as COSV50353398; called by muse, mutect2, varscan2
- HECTD3 | c.2153T>A p.M718K | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV64670182; called by muse, mutect2
- HELZ | c.2357-1G>T p.X786_splice | Splice Site (SNP) | VAF 43/206 reads (21%) | catalogued as COSV62378530; called by muse, mutect2, varscan2
- HGF | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55949722, COSV55959952; called by muse, mutect2
- HHIPL2 | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58565228; called by muse, mutect2, varscan2
- HJURP | c.1726C>A p.R576S | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as COSV64978806, COSV64979720; called by muse, mutect2, varscan2
- HMGCS2 | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 126/1316 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV65567900; called by muse, mutect2
- HNF4G | c.641G>T p.R214L (on ENST00000354370 / NM_001330561.2; = p.R261L on NM_004133.5) | Missense Mutation (SNP) | VAF 155/356 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV62968669; called by muse, mutect2, varscan2
- HNF4G | c.983-1G>T p.X328_splice (on ENST00000354370 / NM_001330561.2; = p.X375_splice on NM_004133.5) | Splice Site (SNP) | VAF 37/84 reads (44%) | catalogued as COSV62968678; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.159G>C p.M53I (on ENST00000354667 / NM_031243.3; = p.M41I on NM_002137.4) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV61159064; called by muse, mutect2
- HOXA2 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV56066333; called by muse, mutect2, varscan2
- HOXA7 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.277); catalogued as rs1384986017, COSV54217748, COSV54217811; called by muse, mutect2, varscan2
- HRNR | c.2626C>G p.H876D | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV64258022; called by muse, mutect2
- HRNR | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 27/353 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as rs777231150, COSV64254091, COSV64258027; called by muse, mutect2
- HSD11B1 | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.585); catalogued as rs200402963, COSV54825830, COSV99808217; called by muse, mutect2, varscan2
- HSD17B6 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 29/531 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV59107044, COSV59107326; called by muse, mutect2
- ICE1 | c.5069G>A p.R1690H | Missense Mutation (SNP) | VAF 97/350 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs749805448, COSV56825189; called by muse, mutect2, varscan2
- IFI16 | c.661C>G p.P221A | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV55534145; called by muse, mutect2, varscan2
- IFT88 | c.569A>T p.Q190L (on ENST00000319980 / NM_001318493.2; = p.Q181L on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60673424; called by muse, mutect2, varscan2
- IGF2R | c.1878C>G p.N626K | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV63629231; called by muse, mutect2, varscan2
- IL17RA | c.511G>T p.G171W | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60053264; called by muse, mutect2, varscan2
- IL18R1 | c.1112-2A>G p.X371_splice | Splice Site (SNP) | VAF 8/75 reads (11%) | catalogued as rs1200486634, COSV52124623; called by muse, varscan2
- IL1RL1 | c.15C>G p.I5M | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.288); catalogued as COSV99294220; called by muse, mutect2
- IL31RA | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV51681659; called by muse, mutect2, varscan2
- IL32 | c.661G>T p.E221* (on ENST00000396890 / NM_001308078.4; = p.E175* on NM_004221.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/384 reads (6%) | catalogued as COSV50404446; called by muse, mutect2
- IMPG1 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100886465; called by muse, mutect2, varscan2
- IMPG1 | c.376T>G p.W126G | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100886469; called by muse, mutect2, varscan2
- INTS6 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV60878108; called by muse, mutect2, varscan2
- ITGA3 | c.1842G>T p.E614D | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.849); catalogued as COSV50311947; called by muse, mutect2, varscan2
- ITGA8 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65228999; called by muse, mutect2, varscan2
- ITGB3 | c.191G>C p.C64S | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM099784, COSV71384061; called by muse, mutect2, varscan2
- ITIH1 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV56255047; called by muse, mutect2
- IVD | c.1012G>A p.A338T (on ENST00000651168; = p.A335T on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV51099199; called by muse, mutect2, varscan2
- KCNH1 | c.2590G>A p.E864K (on ENST00000271751 / NM_172362.3; = p.E837K on NM_002238.4) | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs148523415; called by muse, mutect2, varscan2
- KCNK10 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV56644464, COSV56650420; called by muse, mutect2, varscan2
- KCNQ2 | c.1508C>T p.S503L (on ENST00000359125 / NM_172107.4; = p.S475L on NM_004518.6) | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.95); catalogued as COSV60545101; called by muse, mutect2
- KCNQ2 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV60434114; called by muse, mutect2, varscan2
- KCNQ5 | c.1979C>A p.P660H | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59660308; called by muse, mutect2, varscan2
- KDF1 | c.328A>T p.S110C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV57671383; called by muse, mutect2, varscan2
- KDM3B | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.638); catalogued as COSV100069274, COSV58690782; called by muse, mutect2
- KDM4C | c.921+1G>C p.X307_splice | Splice Site (SNP) | VAF 14/78 reads (18%) | catalogued as COSV67186552; called by muse, mutect2, varscan2
- KIAA1549L | c.725G>C p.R242T (on ENST00000321505; = p.R539T on NM_012194.3) | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55773946; called by muse, mutect2, varscan2
- KIAA1755 | c.2099C>A p.P700H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99642247; called by muse, mutect2, varscan2
- KIF13A | c.5101G>T p.E1701* | Nonsense Mutation (SNP) | VAF 37/88 reads (42%) | catalogued as COSV52451514; called by muse, mutect2, varscan2
- KIF1A | c.4630G>A p.E1544K (on ENST00000320389 / NM_001379639.1; = p.E1536K on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs377032453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF4B | c.1517G>A p.R506K | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV70529330; called by muse, mutect2, varscan2
- KIF4B | c.2998G>T p.A1000S | Missense Mutation (SNP) | VAF 42/287 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV70529338; called by muse, mutect2, varscan2
- KLF10 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV53435566; called by muse, mutect2
- KLHDC10 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59050688, COSV59051738; called by muse, mutect2, varscan2
- KLHL1 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV64772628; called by muse, mutect2
- KLHL1 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 34/280 reads (12%) | catalogued as COSV64772631; called by muse, mutect2, varscan2
- KLHL10 | c.335T>A p.L112Q | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53173206; called by muse, varscan2
- KNG1 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV99405655; called by muse, mutect2
- KRT35 | c.1212G>T p.E404D | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99877820; called by muse, varscan2
- KRT72 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs888721644, COSV53372990; called by muse, mutect2, varscan2
- KRTAP19-7 | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.221); catalogued as COSV58366170; called by muse, mutect2, varscan2
- KRTAP24-1 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261342571, COSV100447463; called by muse, mutect2, varscan2
- KRTAP5-3 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.466); catalogued as rs1457664675, COSV101294515; called by muse, mutect2
- KRTAP9-4 | c.126C>A p.C42* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as rs762012538, COSV61898074; called by muse, mutect2, varscan2
- L1CAM | c.2548-1G>T p.X850_splice | Splice Site (SNP) | VAF 135/343 reads (39%) | catalogued as COSV62828140; called by muse, mutect2, varscan2
- L1CAM | c.1075A>T p.R359W | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV62828144; called by muse, mutect2, varscan2
- LAMA2 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV101370593; called by mutect2, varscan2
- LARS2 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55527695; called by muse, mutect2, varscan2
- LCN15 | c.68T>A p.L23Q | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.928); catalogued as COSV100293467; called by muse, mutect2, varscan2
- LCTL | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58422072; called by muse, mutect2, varscan2
- LEF1 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs1194536526, COSV54467369; called by muse, mutect2, varscan2
- LEPR | c.2673G>T p.K891N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100756384, COSV60755165; called by muse, mutect2, varscan2
- LIG1 | c.139T>A p.S47T | Missense Mutation (SNP) | VAF 87/326 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); catalogued as COSV54391821; called by muse, mutect2, varscan2
- LIMCH1 | c.536A>T p.Y179F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58283952; called by muse, mutect2, varscan2
- LRP1 | c.8474G>T p.C2825F | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99676271; called by muse, mutect2, varscan2
- LRP1 | c.8475C>G p.C2825W | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99676273; called by muse, mutect2, varscan2
- LRP1B | c.13311T>A p.D4437E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV67221177; called by muse, mutect2, varscan2
- LRP1B | c.10574G>C p.G3525A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67221180, COSV99081275; called by muse, mutect2, varscan2
- LRP1B | c.7981G>A p.G2661R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767452254, COSV101256544, COSV67221182; called by mutect2, varscan2
- LRP1B | c.530C>A p.T177N | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as COSV67221186; called by muse, mutect2, varscan2
- LRP2 | c.1817G>C p.G606A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV55553545; called by muse, mutect2, varscan2
- LRRC4C | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 10/103 reads (10%) | catalogued as COSV53425933; called by muse, mutect2, varscan2
- LRRC7 | c.2662A>T p.S888C (on ENST00000651989 / NM_001370785.2; = p.S855C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50459623; called by muse, mutect2, varscan2
- LRRC8D | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV61579390; called by muse, mutect2, varscan2
- LRRTM1 | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54441237; called by muse, mutect2, varscan2
- LYST | c.9682G>T p.V3228L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV67702884, COSV67707055; called by muse, mutect2, varscan2
- MAGEC2 | c.254G>T p.S85I | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.365); catalogued as COSV55999394; called by muse, mutect2, varscan2
- MAGI2 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62660310; called by muse, mutect2
- MAPK10 | c.522G>T p.R174S (on ENST00000359221 / NM_001351625.2; = p.R212S on NM_002753.5) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100174755; called by muse, mutect2
- MARCHF6 | c.1292A>G p.Y431C | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV56881485; called by muse, mutect2
- MARCO | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 15/148 reads (10%) | catalogued as COSV100503635, COSV59054432; called by muse, mutect2, varscan2
- MAS1L | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs760795567, COSV65808937; called by muse, mutect2, varscan2
- MAST4 | c.5966G>T p.R1989M (on ENST00000403625 / NM_001164664.2; = p.R1800M on NM_015183.3) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as COSV55125577; called by muse, mutect2
- MDC1 | c.2809G>T p.V937L | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV64524624; called by muse, mutect2, varscan2
- MDFIC | c.227A>T p.Q76L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV57563883; called by muse, mutect2, varscan2
- MED6 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 12/134 reads (9%) | catalogued as COSV56450223; called by muse, mutect2
- MEGF8 | c.5402G>T p.G1801V (on ENST00000251268 / NM_001271938.2; = p.G1734V on NM_001410.3) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99237083; called by muse, mutect2
- MEGF8 | c.8218G>T p.A2740S (on ENST00000251268 / NM_001271938.2; = p.A2673S on NM_001410.3) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.173); catalogued as COSV52084973; called by muse, mutect2, varscan2
- MEX3B | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61663453; called by muse, mutect2, varscan2
- MFSD11 | c.261-1G>T p.X87_splice | Splice Site (SNP) | VAF 79/635 reads (12%) | catalogued as COSV60623920; called by muse, mutect2, varscan2
- MGAT5B | c.2310G>T p.K770N (on ENST00000569840 / NM_001199172.2; = p.K768N on NM_144677.3) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV56929408; called by muse, mutect2, varscan2
- MIA2 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as rs149036910; called by muse, mutect2, varscan2
- MLH1 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1110879, CM122666, COSV51617219, COSV51618140; called by mutect2, varscan2
- MLLT10 | c.1429G>T p.G477W | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56996028; called by muse, mutect2, varscan2
- MMP16 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV54165465; called by muse, mutect2
- MMP2 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV54601408; called by muse, mutect2, varscan2
- MS4A6A | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.14); catalogued as COSV100124502, COSV100124941, COSV60618722; called by muse, mutect2, varscan2
- MTPN | c.271-1G>T p.X91_splice | Splice Site (SNP) | VAF 14/107 reads (13%) | catalogued as COSV101262977; called by muse, mutect2, varscan2
- MTR | c.1998G>T p.W666C | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63964941; called by muse, mutect2, varscan2
- MUC16 | c.26395C>A p.Q8799K | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.444); catalogued as rs569169440, COSV67466478; called by muse, mutect2, varscan2
- MUC16 | c.22478C>A p.S7493Y | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV67466504; called by muse, mutect2, varscan2
- MUC5B | c.13391G>A p.G4464E | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV71590412; called by muse, mutect2, varscan2
- MUC5B | c.16903C>A p.P5635T | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV71592075, COSV71592645; called by muse, varscan2
- MXRA5 | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99477651; called by muse, mutect2, varscan2
- MYH11 | c.3160G>T p.E1054* | Nonsense Mutation (SNP) | VAF 21/207 reads (10%) | catalogued as COSV55553499; called by muse, mutect2, varscan2
- MYH13 | c.3952G>T p.E1318* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV52829068; called by muse, mutect2, varscan2
- MYH8 | c.3551C>A p.A1184D | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV67965250; called by muse, mutect2, varscan2
- MYO18B | c.6470G>T p.R2157M | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV59134625; called by muse, mutect2, varscan2
- MYO1A | c.1441C>T p.H481Y | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55654035; called by muse, mutect2, varscan2
- MYOD1 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100000298; called by muse, mutect2, varscan2
- MYOM2 | c.2965G>T p.G989* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as rs777160311, COSV50713347; called by muse, mutect2, varscan2
- MYT1L | c.2716C>A p.P906T | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67720457; called by muse, mutect2, varscan2
- MYT1L | c.1297C>A p.L433M | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67720462; called by muse, mutect2, varscan2
- NAP1L3 | c.218G>C p.R73P | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV59075376; called by muse, mutect2
- NAP1L3 | c.216C>A p.S72R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.352); catalogued as COSV59075380; called by muse, mutect2
- NCAM1 | c.1765C>A p.L589I (on ENST00000316851 / NM_181351.5; = p.L579I on NM_000615.7) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV100377975; called by muse, mutect2, varscan2
- NCKAP1 | c.1499C>G p.S500* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV62941190; called by muse, mutect2, varscan2
- NDST3 | c.1418C>G p.P473R | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56619130; called by muse, mutect2
- NELL2 | c.289del p.H97Tfs*2 | Frame Shift Del (DEL) | VAF 15/105 reads (14%) | catalogued as COSV100420230; called by mutect2, pindel, varscan2
- NES | c.3718G>T p.E1240* | Nonsense Mutation (SNP) | VAF 98/429 reads (23%) | catalogued as COSV63961101; called by muse, mutect2, varscan2
- NETO1 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55006935; called by muse, mutect2, varscan2
- NFATC4 | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 48/208 reads (23%) | catalogued as COSV51602964; called by muse, mutect2, varscan2
- NIPAL4 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV61730035; called by muse, mutect2, varscan2
- NLGN1 | c.1110G>T p.Q370H | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs1426206481, COSV64334009; called by muse, mutect2, varscan2
- NLRP7 | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as COSV60174584; called by muse, mutect2, varscan2
- NLRX1 | c.753C>G p.F251L | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52704595; called by muse, mutect2, varscan2
- NLRX1 | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52704628; called by muse, mutect2, varscan2
- NOTCH2 | c.3691C>G p.R1231G | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56691620, COSV56702539; called by muse, mutect2, varscan2
- NOXRED1 | c.348G>T p.L116= | Splice Region (SNP) | VAF 14/52 reads (27%) | catalogued as COSV53628039; called by muse, mutect2, varscan2
- NPNT | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV59753850; called by muse, mutect2
- NR1I2 | c.27G>T p.W9C | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.439); catalogued as COSV61978005, COSV61978348; called by muse, mutect2, varscan2
- NR1I3 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 44/637 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV63467893; called by muse, mutect2
- NRAP | c.1042C>A p.H348N | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.347); catalogued as COSV63490633; called by muse, mutect2, varscan2
- NSF | c.1514A>C p.N505T | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV56574921; called by muse, mutect2, varscan2
- NTNG1 | c.913G>C p.V305L | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV53971836; called by muse, mutect2
- NTRK3 | c.1863G>T p.K621N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100712534, COSV62304520; called by muse, mutect2, varscan2
- NTSR1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs994048236, COSV65138645; called by muse, mutect2, varscan2
- OLFM4 | c.903G>C p.E301D | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as COSV54577416; called by muse, mutect2, varscan2
- OMA1 | c.1077G>T p.W359C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62255547; called by muse, mutect2, varscan2
- OPRM1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.536); catalogued as COSV57676989; called by muse, mutect2, varscan2
- OR10H5 | c.119T>G p.L40R | Missense Mutation (SNP) | VAF 87/291 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100454723; called by muse, mutect2, varscan2
- OR10J3 | c.338G>T p.C113F | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59954342; called by muse, mutect2, varscan2
- OR10K1 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56872001, COSV56872750; called by muse, mutect2, varscan2
- OR10R2 | c.427T>A p.Y143N | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63768768; called by muse, mutect2, varscan2
- OR10Z1 | c.575C>A p.T192K | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV63524869; called by muse, mutect2, varscan2
- OR11L1 | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV63314546, COSV63315451; called by muse, mutect2
- OR14A16 | c.770T>A p.L257Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62926672; called by muse, mutect2, varscan2
- OR1S2 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV56919381; called by muse, varscan2
- OR2F2 | c.62G>A p.W21* | Nonsense Mutation (SNP) | VAF 62/387 reads (16%) | catalogued as COSV101283825; called by muse, mutect2, varscan2
- OR2G2 | c.284T>A p.I95N | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60740587; called by muse, mutect2, varscan2
- OR2L13 | c.724A>T p.T242S | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.469); catalogued as COSV63547393, COSV63552924; called by muse, mutect2, varscan2
- OR2M2 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 72/350 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV62898379; called by muse, varscan2
- OR2T12 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58777503; called by muse, mutect2
- OR2T12 | c.76T>C p.F26L | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs759150557, COSV58777512; called by muse, mutect2, varscan2
- OR2W3 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs1448023356, COSV64456891; called by muse, mutect2, varscan2
- OR2Z1 | c.814A>T p.N272Y | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100136458; called by muse, mutect2, varscan2
- OR4A47 | c.250T>A p.F84I | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); catalogued as COSV71444960; called by muse, mutect2
- OR4C6 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV58604104; called by muse, mutect2, varscan2
- OR4D6 | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV55659798; called by muse, mutect2, varscan2
- OR4K17 | c.906G>T p.W302C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100210695; called by mutect2, varscan2
- OR4L1 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV59849778; called by muse, mutect2, varscan2
- OR51G1 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58969219; called by muse, mutect2, varscan2
- OR51I1 | c.360G>C p.M120I | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs773751717, COSV66507905, COSV66508957; called by muse, mutect2
- OR52J3 | c.820C>A p.H274N | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV66746941; called by muse, mutect2
- OR52N5 | c.560A>T p.Y187F | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV57698889, COSV57699156; called by muse, mutect2, varscan2
- OR5AN1 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100004379; called by muse, mutect2, varscan2
- OR5J2 | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.942); catalogued as COSV56621284, COSV56623849; called by muse, mutect2, varscan2
- OR5K3 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.107); catalogued as COSV67349600, COSV67349718; called by muse, mutect2, varscan2
- OR5M10 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as COSV101595900; called by muse, mutect2
- OR6F1 | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV57467846; called by muse, mutect2, varscan2
- OR8H3 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs558627864, COSV57908991; called by muse, mutect2, varscan2
- OVCH1 | c.1971C>A p.N657K | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV100548782; called by muse, mutect2
- OVCH1 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58962954; called by muse, mutect2, varscan2
- P3H1 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99355330; called by mutect2, varscan2
- PAPOLA | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as rs567161516, COSV99354357; called by muse, mutect2, varscan2
- PARVG | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs921205984; called by mutect2, varscan2
- PCDH10 | c.2855G>T p.R952L | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV52094194; called by muse, mutect2, varscan2
- PCDH11X | c.2791G>T p.D931Y | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53459120, COSV53466685; called by muse, mutect2, varscan2
- PCDH17 | c.3004G>T p.G1002* | Nonsense Mutation (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100931740, COSV100932024; called by muse, mutect2
- PCDH19 | c.3029C>A p.P1010H (on ENST00000373034 / NM_001184880.2; = p.P962H on NM_020766.3) | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as COSV55263053; called by muse, mutect2, varscan2
- PCDH7 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV62338937; called by muse, mutect2, varscan2
- PCDHA12 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56502082; called by muse, mutect2, varscan2
- PCDHA12 | c.1160G>T p.C387F | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100249631, COSV56502090; called by muse, mutect2, varscan2
- PCDHA6 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV65343443; called by muse, mutect2, varscan2
- PCDHB12 | c.2153G>T p.R718M | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV53399345; called by muse, mutect2
- PCDHB15 | c.1856C>A p.A619E | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs17844634, COSV50931745, COSV51003525; called by muse, mutect2, varscan2
- PCDHB3 | c.1061G>C p.S354T | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.233); catalogued as COSV50574077; called by muse, varscan2
- PCDHB3 | c.1333A>C p.N445H | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50574139; called by muse, mutect2, varscan2
- PCDHB5 | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 37/314 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50651838; called by muse, mutect2, varscan2
- PCDHGA1 | c.139A>T p.N47Y | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV65296503; called by muse, mutect2, varscan2
- PCLO | c.9849G>T p.Q3283H | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61635601; called by muse, mutect2, varscan2
- PDCD1LG2 | c.65C>A p.T22K | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV67204623; called by muse, mutect2, varscan2
- PDE1C | c.1475C>A p.A492D | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.498); catalogued as COSV100372855; called by muse, mutect2, varscan2
- PDZRN3 | c.1798C>A p.L600M | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV55199919; called by muse, mutect2
- PDZRN3 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99730415; called by muse, mutect2
- PGLYRP2 | c.1352T>A p.V451E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52993666; called by muse, mutect2
- PGM5 | c.809A>T p.N270I | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67163821; called by muse, mutect2
- PHF21B | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 21/154 reads (14%) | catalogued as COSV57558389; called by muse, mutect2, varscan2
- PHLDB2 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV67311229; called by muse, mutect2, varscan2
- PHOSPHO2 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775918; called by muse, mutect2, varscan2
- PIAS1 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs201183628, COSV99986868; called by muse, mutect2, varscan2
- PITX1 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV54761980; called by muse, mutect2, varscan2
- PIWIL1 | c.1566G>C p.M522I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV55346817; called by muse, varscan2
- PKHD1 | c.2704C>A p.Q902K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100583569, COSV100585157; called by muse, mutect2, varscan2
- PKHD1 | c.2703C>A p.N901K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV100583571; called by muse, mutect2, varscan2
- PKLR | c.227T>A p.L76Q | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100712922, COSV100712937, COSV61360636; called by muse, mutect2, varscan2
- PKLR | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100712940; called by muse, mutect2, varscan2
- PKP2 | c.2261G>A p.R754K | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.408); catalogued as COSV50731018; called by muse, mutect2, varscan2
- PLAU | c.398G>T p.C133F | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV65641369; called by muse, mutect2, varscan2
- PLCE1 | c.1690G>T p.G564C | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53350796; called by muse, mutect2, varscan2
- PLCH2 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs887934400, COSV53943026; called by muse, mutect2, varscan2
- PLCH2 | c.2009A>G p.Y670C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53943037; called by muse, mutect2, varscan2
- PLCL1 | c.3253G>T p.E1085* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV70825180; called by muse, mutect2
- PLD1 | c.2969C>T p.T990I | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV60568104; called by muse, mutect2, varscan2
- PLXNA1 | c.287A>T p.Y96F | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52526174; called by muse, mutect2, varscan2
- PLXNC1 | c.2659G>A p.G887R | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1414464957, COSV51575436; called by muse, mutect2, varscan2
- PNLIPRP3 | c.443T>A p.I148N | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65048153; called by muse, mutect2, varscan2
- PNPT1 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 7/92 reads (8%) | catalogued as COSV53177343; called by muse, mutect2
- POLE | c.1718G>T p.R573L | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as COSV57680358; called by muse, mutect2
- POLR3A | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as rs1012934044, COSV64931050; called by muse, mutect2, varscan2
- POTEH | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 89/581 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.548); catalogued as COSV58882863; called by muse, varscan2
- PPEF2 | c.2191G>C p.G731R | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV54422512; called by muse, mutect2
- PRAMEF1 | c.140G>T p.R47I | Missense Mutation (SNP) | VAF 42/352 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60009356; called by muse, mutect2, varscan2
- PREPL | c.343G>T p.V115F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs1241633455, COSV53216698; ClinVar: uncertain significance; called by muse, mutect2
- PRKD1 | c.2539G>T p.D847Y | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59558319; called by muse, mutect2, varscan2
- PROM1 | c.1207C>A p.Q403K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV71699443; called by muse, mutect2, varscan2
- PRRX1 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV53413814; called by muse, mutect2, varscan2
- PSKH2 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.01); catalogued as COSV52609254; called by muse, mutect2
- PTK7 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57848680; called by muse, mutect2, varscan2
- PTPN23 | c.4105C>A p.R1369S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as COSV55544624, COSV55544658; called by muse, mutect2
- PTPRD | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs745977244, COSV61930536; called by muse, mutect2, varscan2
- PTPRF | c.3524G>C p.R1175P | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100741000, COSV63446499; called by muse, mutect2, varscan2
- RAB6C | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101308521; called by muse, mutect2, varscan2
- RAB9B | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as COSV54587585; called by muse, mutect2, varscan2
- RBBP6 | c.2446G>A p.V816I | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV60505173; called by muse, mutect2, varscan2
- RBFOX2 | c.241A>G p.N81D (on ENST00000438146 / NM_001349995.2; = p.N11D on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.979); catalogued as COSV53264600; called by muse, mutect2, varscan2
- RCC1L | c.1096G>T p.G366W | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782599407, COSV100326933; called by muse, mutect2, varscan2
- RDH16 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 16/166 reads (10%) | catalogued as COSV62458140; called by muse, mutect2
- REG1B | c.474C>A p.F158L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59304492, COSV59304684; called by muse, varscan2
- REG1B | c.65-1G>T p.X22_splice | Splice Site (SNP) | VAF 26/215 reads (12%) | catalogued as COSV59305645; called by mutect2, varscan2
- REG3A | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV59409611; called by muse, mutect2, varscan2
- RELN | c.2681G>A p.C894Y | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59002606; called by muse, mutect2, varscan2
- RESF1 | c.3603G>T p.E1201D | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV57022154; called by muse, mutect2
- RFX1 | c.2724G>C p.E908D | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as COSV54329955; called by muse, mutect2
- RGS1 | c.54C>A p.F18L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1334107111, COSV66505354; called by muse, mutect2, varscan2
- RIMS4 | c.105C>A p.S35R | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV65719721; called by muse, mutect2, varscan2
- RIPOR2 | c.1608T>A p.D536E | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0.047); catalogued as COSV52422032; called by muse, mutect2, varscan2
- RNASE10 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as COSV100116170; called by muse, mutect2, varscan2
- RNASE10 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100116176; called by muse, mutect2, varscan2
- ROR2 | c.1486G>T p.A496S | Missense Mutation (SNP) | VAF 196/683 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.057); catalogued as COSV65219176; called by muse, mutect2, varscan2
- RPL14 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59083020; called by muse, mutect2
- RTBDN | c.204G>T p.E68D (on ENST00000393233 / NM_001270444.1; = p.E100D on NM_031429.2) | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.607); catalogued as COSV59806343; called by muse, mutect2
- RYR2 | c.14658C>T p.T4886= | Splice Region (SNP) | VAF 30/161 reads (19%) | catalogued as COSV63686064; called by muse, varscan2
- SACS | c.8167G>T p.V2723F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101207511; called by muse, mutect2
- SATB2 | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV53483853; called by muse, mutect2
- SBSPON | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 159/544 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.154); catalogued as COSV52075980; called by muse, mutect2, varscan2
- SCN1A | c.3235G>C p.V1079L (on ENST00000303395 / NM_001202435.3; = p.V1068L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV57670349; called by muse, mutect2, varscan2
- SCRN1 | c.701A>T p.D234V | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV54130840; called by muse, mutect2, varscan2
- SDHAF2 | c.10T>C p.S4P | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV57099259; called by muse, mutect2
- SDS | c.298A>C p.K100Q | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV57453531; called by muse, mutect2
- SEC14L5 | c.1376G>C p.G459A | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52038509; called by muse, mutect2
- SEC61A2 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV53650587; called by muse, mutect2, varscan2
- SENP6 | c.2928G>T p.M976I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV64187431; called by mutect2, varscan2
- SEPTIN4 | c.354C>A p.S118R | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); catalogued as COSV58727889; called by muse, mutect2, varscan2
- SEPTIN5 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 109/247 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63530623; called by muse, mutect2, varscan2
- SERPINA12 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV57943690; called by muse, mutect2, varscan2
- SERPINB12 | c.356A>T p.Y119F | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.545); catalogued as COSV54033211; called by muse, mutect2, varscan2
- SERPINI2 | c.1142-1G>A p.X381_splice | Splice Site (SNP) | VAF 5/17 reads (29%) | catalogued as rs747834843, COSV52987598, COSV99248049; called by muse, mutect2, varscan2
- SESTD1 | c.1150C>A p.H384N | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV58930657; called by muse, mutect2, varscan2
- SETBP1 | c.2497A>T p.R833* | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | catalogued as COSV56322198; called by muse, mutect2
- SF3B2 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.044); catalogued as COSV59428205; called by muse, mutect2, varscan2
- SH3TC2 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs142488510, COSV60463331; called by muse, mutect2, varscan2
- SHROOM2 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as COSV66606705; called by muse, mutect2, varscan2
- SHROOM3 | c.2605G>A p.G869R | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1260796052, COSV56029376; called by muse, mutect2, varscan2
- SIGLEC10 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV59481789; called by muse, mutect2, varscan2
- SLAMF8 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 86/362 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV56988436; called by muse, mutect2, varscan2
- SLAMF9 | c.665-2A>T p.X222_splice | Splice Site (SNP) | VAF 14/101 reads (14%) | catalogued as COSV100928147; called by muse, mutect2
- SLC12A5 | c.1793C>T p.A598V (on ENST00000454036 / NM_001134771.2; = p.A575V on NM_020708.5) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV54793849; called by muse, mutect2, varscan2
- SLC12A7 | c.207G>T p.M69I | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV53757323; called by muse, mutect2
- SLC22A11 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 106/346 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as rs1390117057, COSV57253201; called by muse, mutect2, varscan2
- SLC22A25 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100123697; called by muse, mutect2, varscan2
- SLC26A3 | c.539C>A p.A180E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV60640343; called by muse, mutect2, varscan2
- SLC26A7 | c.542C>A p.A181E | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52593520; called by muse, mutect2
- SLC26A7 | c.1161C>A p.C387* | Nonsense Mutation (SNP) | VAF 40/139 reads (29%) | catalogued as COSV52590218, COSV52593540; called by muse, mutect2, varscan2
- SLC27A1 | c.1496T>A p.L499Q | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV53097461; called by muse, mutect2
- SLC30A1 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV65361036; called by muse, mutect2, varscan2
- SLC35B1 | c.457G>T p.G153C (on ENST00000649906; = p.G116C on NM_005827.4) | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53602093, COSV53603018; called by muse, mutect2
- SLC36A1 | c.883G>C p.G295R | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54653838; called by muse, mutect2, varscan2
- SLC4A1 | c.535A>C p.T179P | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99293429; called by muse, mutect2, varscan2
- SLC9A1 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 60/266 reads (23%) | catalogued as COSV99849789; called by muse, mutect2, varscan2
- SLITRK5 | c.923C>A p.T308N | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as COSV61522964; called by muse, mutect2
- SMAP2 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65532334; called by muse, mutect2, varscan2
- SMURF1 | c.1287G>T p.M429I | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV63157533; called by muse, mutect2, varscan2
- SND1 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.065); catalogued as COSV100690619; called by muse, mutect2
- SND1 | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100690621; called by muse, mutect2
- SNIP1 | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV56166565; called by muse, mutect2
- SNTG1 | c.603G>C p.K201N | Missense Mutation (SNP) | VAF 126/320 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV52444200; called by muse, varscan2
- SNX1 | c.160-1G>T p.X54_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | catalogued as COSV56038318; called by muse, mutect2, varscan2
- SNX25 | c.200T>C p.L67S | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396737509, COSV53014522; called by muse, mutect2, varscan2
- SOWAHC | c.1112G>T p.R371M | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61780303; called by muse, mutect2, varscan2
- SOX6 | c.2390G>T p.G797V (on ENST00000528429 / NM_001145819.2; = p.G770V on NM_017508.3) | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57046104; called by muse, mutect2, varscan2
- SP110 | c.1049-1G>T p.X350_splice | Splice Site (SNP) | VAF 26/201 reads (13%) | catalogued as COSV51251036; called by muse, mutect2, varscan2
- SPANXN2 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.988); catalogued as COSV65128423; called by muse, mutect2, varscan2
- SPATA31A3 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 87/1032 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs368133001; called by muse, mutect2
- SPEF2 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56796933; called by muse, mutect2, varscan2
- SPESP1 | c.394G>C p.V132L | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV52988921; called by muse, mutect2
- SPHKAP | c.3194C>A p.P1065H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV60879255, COSV60889955; called by muse, mutect2
- SPINK13 | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV101268305; called by muse, mutect2, varscan2
- SPRY4 | c.697G>T p.A233S (on ENST00000434127 / NM_001127496.3; = p.A256S on NM_030964.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.325); catalogued as COSV100702209, COSV100702211; called by mutect2, varscan2
- SPTA1 | c.2332C>A p.L778M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63751430, COSV63753232; called by muse, mutect2, varscan2
- SPTAN1 | c.4076G>T p.R1359L | Missense Mutation (SNP) | VAF 92/397 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.107); catalogued as COSV63987184; called by muse, mutect2, varscan2
- SPTB | c.2109G>T p.M703I | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as COSV67631857; called by muse, mutect2, varscan2
- SRGAP1 | c.2302G>T p.A768S | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.199); catalogued as COSV61898100; called by muse, varscan2
- ST6GAL2 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | PolyPhen possibly damaging (0.786); catalogued as COSV64527778, COSV64528359; called by muse, mutect2, varscan2
- SUGP1 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs796157071, COSV53235416; called by muse, mutect2, varscan2
- SUSD6 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61365437; called by muse, mutect2, varscan2
- SV2C | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 62/255 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV59220194; called by muse, varscan2
- SYMPK | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as COSV55571836, COSV55575022; called by muse, mutect2, varscan2
- SYNE1 | c.24911C>A p.P8304H (on ENST00000367255 / NM_182961.4; = p.P8233H on NM_033071.3) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54983861; called by muse, mutect2, varscan2
- SYNPO2 | c.2710A>T p.T904S | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.508); catalogued as COSV61110956; called by muse, mutect2
- SYT10 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV57340633; called by muse, mutect2, varscan2
- SYT14 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.258); catalogued as COSV55054401; called by muse, mutect2, varscan2
- SYT9 | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59618484; called by muse, mutect2, varscan2
- TAF1 | c.737A>C p.H246P (on ENST00000373790 / NM_138923.4; = p.H267P on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV52113606; called by muse, mutect2, varscan2
- TAGLN3 | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56327943, COSV56329244; called by muse, mutect2
- TASOR2 | c.2010G>T p.E670D | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV60167514; called by muse, mutect2
- TASOR2 | c.5441G>T p.G1814V | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60167519; called by muse, mutect2
- TATDN1 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52679520; called by muse, mutect2, varscan2
- TBL1X | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV54280241; called by muse, mutect2, varscan2
- TCF23 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 146/404 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV99940358; called by muse, mutect2, varscan2
- TCHH | c.4998C>A p.D1666E | Missense Mutation (SNP) | VAF 173/369 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV64274848; called by muse, mutect2, varscan2
- TCTEX1D1 | c.440G>T p.R147I | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51075707, COSV51076159; called by muse, mutect2, varscan2
- TCTN2 | c.943A>T p.N315Y | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57633007; called by muse, mutect2
- TENM1 | c.7411C>A p.P2471T | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV64432070; called by muse, mutect2, varscan2
- TENT5D | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100383047, COSV57636713; called by muse, mutect2, varscan2
- TF | c.1424G>C p.R475T | Missense Mutation (SNP) | VAF 107/363 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.647); catalogued as COSV53920384; called by muse, mutect2, varscan2
- TFDP3 | c.487C>A p.R163S | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59536346, COSV59536950; called by muse, mutect2, varscan2
- TG | c.6461G>C p.C2154S | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as CM063193, COSV55076438; called by muse, mutect2, varscan2
- TGFB2 | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM1210057, COSV65108222, COSV65109328; called by muse, mutect2, varscan2
- THG1L | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV51452907; called by muse, mutect2
- THRAP3 | c.1945A>G p.T649A | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63567828; called by muse, mutect2
- TLL2 | c.1349A>G p.N450S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.061); catalogued as rs1205876498, COSV63572492; called by muse, mutect2, varscan2
- TM6SF2 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.752); catalogued as COSV52269513; called by muse, mutect2, varscan2
- TMEM130 | c.1204G>A p.G402R (on ENST00000416379 / NM_001134450.2; = p.G390R on NM_152913.3) | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV59559220; called by muse, mutect2, varscan2
- TMEM82 | c.602C>A p.P201H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99606677; called by muse, mutect2
- TMEM87B | c.1054G>T p.V352F | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs761998812, COSV51715298; called by muse, mutect2, varscan2
- TMEM8B | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1039944131, COSV65076659; called by muse, mutect2, varscan2
- TMPRSS11E | c.290G>T p.R97M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV100542186, COSV59519111; called by muse, mutect2, varscan2
- TMPRSS7 | c.1495C>G p.Q499E (on ENST00000452346; = p.Q373E on NM_001042575.2) | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV69980705; called by muse, mutect2
- TNFSF8 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56342525; called by muse, mutect2, varscan2
- TNN | c.2569C>A p.P857T | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53426390; called by muse, mutect2, varscan2
- TNN | c.2857G>T p.V953L | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.403); catalogued as rs372170240, COSV53426400; called by muse, mutect2, varscan2
- TNNT3 | c.187G>T p.E63* (on ENST00000397301 / NM_001367846.1; = p.E52* on NM_006757.4) | Nonsense Mutation (SNP) | VAF 32/189 reads (17%) | catalogued as COSV99548560; called by muse, mutect2, varscan2
- TNR | c.3661C>T p.Q1221* | Nonsense Mutation (SNP) | VAF 29/112 reads (26%) | catalogued as COSV54885890; called by muse, mutect2, varscan2
- TOLLIP | c.766C>A p.Q256K | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as COSV99719609; called by muse, mutect2
- TRAF3IP3 | c.106C>A p.R36S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs981440427, COSV50550785, COSV50553080; called by muse, mutect2, varscan2
- TRIM56 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as COSV100047447; called by muse, mutect2, varscan2
- TRIM56 | c.1663G>T p.V555L | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); catalogued as COSV100047449; called by muse, mutect2, varscan2
- TRIM63 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.173); catalogued as COSV65328475; called by muse, mutect2, varscan2
- TRIM9 | c.2065G>T p.V689L | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53612814; called by muse, mutect2, varscan2
- TRIML1 | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV60194308; called by muse, mutect2, varscan2
- TROAP | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV57744116; called by muse, mutect2, varscan2
- TSHZ3 | c.2848C>A p.L950M | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53667643; called by muse, mutect2, varscan2
- TSHZ3 | c.1628G>C p.S543T | Missense Mutation (SNP) | VAF 43/326 reads (13%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.931); catalogued as COSV53671825; called by muse, mutect2, varscan2
- TTN | c.20168G>T p.R6723L (on ENST00000591111; = p.R5796L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | PolyPhen benign (0.138); catalogued as rs754476903; called by muse, mutect2, varscan2
- TUBA1A | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs1565627084, CM125541, COSV55497840; called by muse, mutect2, varscan2
- TYR | c.963C>A p.C321* | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | catalogued as COSV54475695; called by muse, mutect2, varscan2
- UBA6 | c.1316G>C p.R439P | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.307); catalogued as COSV59176690, COSV59177291; called by muse, mutect2, varscan2
- UBE2O | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 47/375 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs764459575, COSV60063234; called by muse, mutect2, varscan2
- UBE2R2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV54289631; called by muse, mutect2, varscan2
- UGT2B4 | c.1386C>A p.F462L | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs745780826, COSV59317246, COSV59320314; called by muse, varscan2
- UNC119 | c.610+7G>T | Splice Region (SNP) | VAF 32/106 reads (30%) | catalogued as COSV99971737; called by muse, mutect2, varscan2
- UNC79 | c.3591G>T p.R1197S (on ENST00000393151 / NM_001346218.2; = p.R1020S on NM_020818.5) | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV56388291; called by muse, mutect2
- URGCP | c.217C>T p.L73F (on ENST00000453200 / NM_001077663.3; = p.L64F on NM_017920.4) | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.511); catalogued as COSV56247831; called by muse, mutect2, varscan2
- USF3 | c.3145C>T p.Q1049* | Nonsense Mutation (SNP) | VAF 32/206 reads (16%) | catalogued as COSV57072780; called by muse, mutect2, varscan2
- USF3 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV57072788; called by muse, mutect2, varscan2
- USH2A | c.15227G>T p.R5076I | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56331616, COSV56370180; called by muse, mutect2, varscan2
- USH2A | c.2438G>A p.G813E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330954314, COSV100240138, COSV56370519; called by muse, mutect2, varscan2
- USP29 | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as COSV54142695; called by muse, mutect2, varscan2
- USP31 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54852273, COSV54854101; called by muse, mutect2, varscan2
- USP40 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV52480990; called by muse, mutect2, varscan2
- USPL1 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54999984; called by muse, mutect2, varscan2
- UVRAG | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV62104326, COSV62105871; called by muse, mutect2, varscan2
- VCAN | c.7951C>A p.H2651N | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as COSV54105247; called by muse, mutect2, varscan2
- VCAN | c.9592C>A p.R3198S | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54099409, COSV54105278; called by muse, mutect2, varscan2
- VCP | c.787G>T p.G263* | Nonsense Mutation (SNP) | VAF 46/400 reads (12%) | catalogued as COSV62720562; called by muse, mutect2, varscan2
- VIL1 | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50288180; called by muse, mutect2, varscan2
- WDFY3 | c.8843C>T p.P2948L | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55701149; called by muse, mutect2, varscan2
- WDR41 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.441); catalogued as COSV56998839; called by muse, mutect2, varscan2
- WSCD2 | c.1346-1G>C p.X449_splice | Splice Site (SNP) | VAF 12/122 reads (10%) | catalogued as COSV54583003; called by muse, mutect2
- WWC3 | c.974G>T p.R325M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66503423; called by muse, mutect2, varscan2
- WWC3 | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as rs753501417, COSV66503432; called by muse, mutect2
- XIRP2 | c.2470C>T p.H824Y (on ENST00000628543; = p.H999Y on NM_152381.6) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54700953; called by muse, mutect2, varscan2
- ZBTB16 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV60093163, COSV60100543; called by muse, mutect2, varscan2
- ZBTB18 | c.536A>T p.E179V | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV62397010; called by muse, mutect2, varscan2
- ZC3H12C | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV53708896; called by muse, mutect2, varscan2
- ZC3H12C | c.2369G>C p.R790P | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.608); catalogued as COSV53708908, COSV53710365; called by muse, mutect2, varscan2
- ZEB2 | c.2154C>A p.N718K | Missense Mutation (SNP) | VAF 43/327 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV57956962; called by muse, mutect2, varscan2
- ZEB2 | c.1567A>G p.K523E | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57956972, COSV57957267; called by muse, mutect2, varscan2
- ZEB2 | c.144G>C p.E48D | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV57952810, COSV57956984; called by muse, mutect2, varscan2
- ZFHX4 | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV50808738; called by muse, mutect2
- ZFP57 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100971876, COSV65306160; called by muse, mutect2, varscan2
- ZIM3 | c.1417T>C p.*473Qext*24 | Nonstop Mutation (SNP) | VAF 12/154 reads (8%) | catalogued as rs1239219077, COSV54142710; called by muse, mutect2
- ZIM3 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1210324853, COSV54142721; called by muse, mutect2, varscan2
- ZNF154 | c.1223C>A p.T408N | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs1222248309, COSV101377445; called by muse, mutect2
- ZNF268 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV57212924; called by muse, mutect2, varscan2
- ZNF273 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148564376; called by muse, mutect2, varscan2
- ZNF273 | c.1000A>T p.T334S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV100139380; called by muse, mutect2, varscan2
- ZNF423 | c.2684G>T p.G895V (on ENST00000563137 / NM_001379286.1; = p.G887V on NM_015069.4) | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV52186628, COSV52189049; called by muse, mutect2, varscan2
- ZNF423 | c.1939C>T p.L647F (on ENST00000563137 / NM_001379286.1; = p.L639F on NM_015069.4) | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.811); catalogued as rs1186676819, COSV52189073; called by muse, mutect2, varscan2
- ZNF438 | c.1453A>C p.N485H | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV59195244; called by muse, mutect2, varscan2
- ZNF442 | c.1670C>G p.T557S | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54421547; called by muse, mutect2
- ZNF479 | c.884G>T p.R295I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV100482705, COSV58635981, COSV58638464; called by muse, mutect2
- ZNF496 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745941752, COSV54177301; called by muse, mutect2, varscan2
- ZNF521 | c.3055G>T p.G1019C | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64127037; called by muse, mutect2, varscan2
- ZNF521 | c.2037G>T p.L679F | Missense Mutation (SNP) | VAF 64/448 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); catalogued as COSV64127042; called by muse, varscan2
- ZNF558 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV100037970; called by muse, mutect2, varscan2
- ZNF558 | c.976G>T p.G326W | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100037973; called by muse, mutect2, varscan2
- ZNF560 | c.1489T>A p.F497I | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56867904; called by muse, mutect2
- ZNF598 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1015969283, COSV70910633; called by muse, mutect2, varscan2
- ZNF680 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV59014432, COSV59015812; called by muse, mutect2
- ZNF699 | c.782G>T p.S261I | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV58025666; called by muse, mutect2, varscan2
- ZNF80 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV57360783; called by muse, mutect2, varscan2
- ZNF804B | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.314); catalogued as COSV60828438, COSV60847716; called by muse, mutect2, varscan2
- ZPLD1 | c.1018G>T p.A340S (on ENST00000466937 / NM_001329788.1; = p.A356S on NM_175056.2) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.065); catalogued as rs1399425816, COSV60353588; called by muse, mutect2, varscan2
- ZSWIM2 | c.944A>T p.Q315L | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54575533; called by muse, mutect2
- ZZZ3 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV66232772; called by muse, mutect2, varscan2
- ANKEF1 | c.1890dup p.A631Cfs*6 | Frame Shift Ins (INS) | VAF 36/108 reads (33%) | called by mutect2, pindel, varscan2
- CASP14 | c.579del p.D193Efs*14 | Frame Shift Del (DEL) | VAF 16/129 reads (12%) | called by mutect2, pindel, varscan2
- CDS2 | c.797del p.G266Afs*15 | Frame Shift Del (DEL) | VAF 28/151 reads (19%) | called by mutect2, pindel, varscan2
- CLU | c.80C>G p.S27* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- CRYBA2 | c.542del p.G181Afs*27 | Frame Shift Del (DEL) | VAF 15/123 reads (12%) | called by mutect2, pindel, varscan2
- DGKB | c.266dup p.N89Kfs*7 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- DIO2 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.27); called by muse, mutect2
- DST | c.2490del p.K831Sfs*13 (on ENST00000361203 / NM_001374722.1; = p.K505Sfs*13 on NM_001723.6) | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- ELAVL4 | c.420del p.T142Pfs*2 | Frame Shift Del (DEL) | VAF 38/209 reads (18%) | called by mutect2, pindel, varscan2
- FLI1 | c.1215dup p.S406Ifs*36 | Frame Shift Ins (INS) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- FRG2C | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 25/341 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.176); called by muse, mutect2
- GRID2 | c.2632del p.H878Ifs*4 | Frame Shift Del (DEL) | VAF 42/147 reads (29%) | called by mutect2, pindel, varscan2
- IGHV1OR15-9 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- IGHV3-38 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- IMPG2 | c.1266del p.S423Qfs*36 | Frame Shift Del (DEL) | VAF 27/96 reads (28%) | called by mutect2, pindel, varscan2
- KCNE1 | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by mutect2, varscan2
- KLHL5 | c.1810del p.A604Qfs*3 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- KMT2C | c.11510dup p.L3837Ffs*9 | Frame Shift Ins (INS) | VAF 22/227 reads (10%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.418del p.R140Vfs*39 | Frame Shift Del (DEL) | VAF 26/156 reads (17%) | called by mutect2, varscan2
- MARCO | c.459dup p.G154Rfs*23 | Frame Shift Ins (INS) | VAF 20/191 reads (10%) | called by mutect2, varscan2
- MUC17 | c.2793del p.D931Efs*6 | Frame Shift Del (DEL) | VAF 138/849 reads (16%) | called by mutect2, pindel, varscan2
- PCDHGA11 | c.785dup p.L263Afs*4 | Frame Shift Ins (INS) | VAF 32/307 reads (10%) | called by mutect2, pindel, varscan2
- PLA2G4C | c.789del p.G264Vfs*22 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- PLCG2 | c.921_922insT p.A308Cfs*21 | Frame Shift Ins (INS) | VAF 20/81 reads (25%) | called by muse*, mutect2, varscan2*
- POLR2A | c.2588G>T p.R863L | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- POT1 | c.1793-2A>T p.X598_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- POTEA | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- PRAMEF20 | c.644A>G p.N215S | Missense Mutation (SNP) | VAF 24/663 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- PRAMEF8 | c.1057C>A p.L353M | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRDX6 | c.413del p.G138Vfs*6 | Frame Shift Del (DEL) | VAF 23/184 reads (13%) | called by mutect2, pindel, varscan2
- RHOXF2B | c.221del p.G74Afs*98 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | called by mutect2, varscan2
- SFTPD | c.842del p.C281Sfs*25 | Frame Shift Del (DEL) | VAF 28/124 reads (23%) | called by pindel, varscan2
- SPATA17 | c.684del p.S229Lfs*23 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- TNFRSF18 | c.464del p.P155Qfs*12 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, varscan2
- TRAV20 | c.245G>T p.R82M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TSBP1 | c.1446dup p.E483Rfs*7 (on ENST00000617061; = p.E488Rfs*7 on NM_006781.5) | Frame Shift Ins (INS) | VAF 74/240 reads (31%) | called by mutect2, pindel, varscan2
- TSHR | c.1098del p.F366Lfs*46 | Frame Shift Del (DEL) | VAF 22/195 reads (11%) | called by mutect2, pindel, varscan2
- TTC21A | c.1103T>A p.M368K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2
- TTC21A | c.1104G>T p.M368I | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- UQCRC2 | c.1331dup p.L444Ffs*8 | Frame Shift Ins (INS) | VAF 36/154 reads (23%) | called by mutect2, pindel, varscan2
- USH2A | c.6665_6666del p.T2222Rfs*8 | Frame Shift Del (DEL) | VAF 28/178 reads (16%) | called by pindel, varscan2
- WDR91 | c.1816del p.E606Rfs*77 | Frame Shift Del (DEL) | VAF 71/330 reads (22%) | called by mutect2, pindel, varscan2
- ABCC2 | c.4275G>T p.G1425= | Silent (SNP) | VAF 22/206 reads (11%) | catalogued as COSV64986250; called by muse, mutect2
211 further variants in this file (0 protein-altering or splice-affecting, 186 silent, 25 other) are not listed here.
